Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4O5, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4O5-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: PARIETAL PLEURA, RIGHT, RESECTION -

- A. DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE, FOCAL TUBULOPAPILLARY PATTERN INVADING INTO THE ADIPOSE TISSUE AND SKELETAL MUSCLES.
- B. FOCAL FOREIGN BODY GIANT CELL REACTION CONTAINING REFRACTILE MATERIAL SUGGESTIVE OF PRIOR SURGERY.

PART 2: SOFT TISSUE, OLD CHEST TUBE SITE, BIOPSY -

- A. DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE WITH FOCAL TUBULOPAPILLARY PATTERN INVADING INTO THE SKELETAL MUSCLES.
- B. FOCAL PERINEURAL INVASION PRESENT.
- C. FOCAL FOREIGN BODY GIANT CELL REACTION CONSISTENT WITH PRIOR SURGERY SITE.

PART 3: SOFT TISSUE, CHEST WALL, RESECTION -

- A. DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE WITH FOCAL FOREIGN BODY GIANT CELL REACTION SUGGESTIVE OF PRIOR SURGERY.
- B. MESOTHELIOMA EXTENDS INTO THE SURROUNDING FAT, INVOLVES SKELETAL MUSCLES AND PERIOSTEUM OF THE RIB, HOWEVER RIB IS FREE OF MALIGNANCY.
- C. PLEURAL MARGIN OF RESECTION INVOLVED BY MESOTHELIOMA.
- D. ANTERIOR CHEST WALL ADIPOSE TISSUE AND SKELETAL MUSCLES MARGIN - FREE OF MALIGNANCY.

PART 4: SEGMENT OF RIB, SIXTH, RESECTION -

- SEGMENT OF RIB AND SKELETAL MUSCLES - FREE OF MALIGNANCY.

PART 5: SOFT TISSUE, MEDIASTINAL PLEURA, RESECTION -

- DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE WITH FOCAL FOREIGN BODY GIANT CELL REACTION CONSISTENT WITH PRIOR SURGERY AND INVADING INTO THE FAT.

PART 6: SOFT TISSUE, MEDIASTINAL PLEURA AND THYMUS, RESECTION -

- A. DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE WITH TUBULOPAPILLARY PATTERN.
- B. FOCAL FOREIGN BODY GIANT CELL REACTION CONSISTENT WITH PRIOR SURGERY.
- C. MESOTHELIOMA IS INFILTRATING INTO THE ADIPOSE TISSUE.
- D. AJCC 7TH EDITION PATHOLOGIC TUMOR STAGE: pT3 NX MX AND HISTOLOGIC GRADE G2.

COMMENT:

Immunostains performed on the block 3C reveal the following findings:

TTF-1 - negative
B72.3 (TG72) - negative
BerEP4 - negative
LeuM1 - negative
cytokeratin 5/6 - positive
calretinin - positive
D2 40 - focal positive staining
WT1 - positive

In addition mucicarmine stain is negative. It shows occasional focal PAS stain with diastase positive staining.

In view of these findings, the diagnosis of mesothelioma is supported.

Select slides from this case are reviewed with

agrees with the above interpretation.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY MESOTHELIOMA

SPECIMEN:

Pleura
Other: rib
Pleurectomy
Disrupted
Right
Parietal pleura
Visceral pleura
Other: rib
Diffuse

PROCEDURE:

SPECIMEN INTEGRITY:

SPECIMEN LATERALITY:

TUMOR SITE:

TUMOR FOCALITY:

HISTOLOGIC TYPE:

TUMOR EXTENSION:

Epithelioid mesothelioma
Parietal pleura with focal involvement of ipsilateral visceral pleura
Diffuse or multiple foci invading soft tissue of chest wall
Cannot be assessed
Not applicable

MARGINS:

TREATMENT EFFECT:

PATHOLOGIC STAGING (pTNM)

pT3
pNX
Number examined: 0
pM Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

ANCILLARY STUDIES:

None identified
Immunohistochemical stain(s)
Histochemical stain(s)

ICD-O-3
Mesothelioma, epithelioid, NOS
9052/3

Site: pleura, NOS C38.4

12/25/12

Site Discrepancy		☒

Source: NCI Genomic Data Commons file 03861e53-f50c-4d18-ad7a-f30cf4652b58 (TCGA-LK-A4O5.3592A658-BEB9-4DC5-9B27-D13D1552322A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).